Somatic mutation profile of tumor specimen 0DP6HZ from CCDI case PBCCRL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Hemangioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.3 years (6,336 days).
Specimen 0DP6HZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3892afa-3ea5-4e8b-9922-6f0e9a4edc3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90f7134b-8bb5-49b5-b15d-1ef8d014748c

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BX276092.9 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.279); catalogued as rs1452780421; called by muse, mutect2
- COL13A1 | c.1102G>T p.G368W (on ENST00000398978 / NM_001130103.2; = p.G311W on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62570480; called by muse, mutect2
- TEX13D | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs1364180197, COSV69794684; called by muse, mutect2
- TEX13D | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV69794686; called by muse, mutect2
- TSC22D1 | c.2062C>G p.Q688E | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV71775867; called by muse, mutect2
- ADAMTS16 | c.1625G>A p.W542* | Nonsense Mutation (SNP) | VAF 26/546 reads (5%) | called by muse, mutect2
- ADD3 | c.861G>A p.K287= | Splice Region (SNP) | VAF 70/600 reads (12%) | called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 31/704 reads (4%) | called by muse, mutect2
- STXBP5 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 19/312 reads (6%) | called by muse, mutect2
- RNF168 | c.-47T>A | 5'UTR (SNP) | VAF 33/270 reads (12%) | called by muse, mutect2, varscan2
- UQCRHL | c.-72A>G | 5'UTR (SNP) | VAF 8/158 reads (5%) | catalogued as rs897616552; called by muse, mutect2
- YAF2 | c.152+26951G>T | Intron (SNP) | VAF 25/458 reads (5%) | catalogued as rs1041371904, COSV100586253; called by muse, mutect2
